Somatic mutation profile of tumor specimen MP2PRT-PAUNCU-TMP1-A (aliquot MP2PRT-PAUNCU-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUNCU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (843 days).
Specimen MP2PRT-PAUNCU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1edc9f-3309-4691-bf48-34f92e612f74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNCU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNCU-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69e4a292-e23a-4119-b647-526def322b00

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 1, Nonsense Mutation 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC39 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 16/404 reads (4%) | catalogued as COSV56482756; called by muse, mutect2
- COL6A6 | c.2155C>T p.R719W | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750521607; called by muse, mutect2
- TTN | c.43263G>C p.L14421F (on ENST00000591111; = p.L6997F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/369 reads (4%) | PolyPhen benign (0.074); catalogued as COSV100623206; called by muse, mutect2
- UGT2B28 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371664274, COSV59430439; called by muse, mutect2, varscan2
- IGKV2D-24 | c.359_360insCTCC p.*121Sfs*? | Frame Shift Ins (INS) | VAF 37/62 reads (60%) | called by pindel, varscan2*
- IGKV2D-24 | chr2:90005629 TCA>CTCCGGT | Missense Mutation (INS) | VAF 18/38 reads (47%) | called by pindel, varscan2*
- MCHR2 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCDHA8 | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 30/563 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); called by muse, mutect2
- PFKM | c.1192-1G>C p.X398_splice | Splice Site (SNP) | VAF 34/275 reads (12%) | called by muse, mutect2, varscan2
- POLE | c.4607T>C p.L1536P | Missense Mutation (SNP) | VAF 99/561 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRHDE | c.3035A>G p.D1012G | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, varscan2
- TRIB2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TRIM33 | c.1386T>G p.D462E | Missense Mutation (SNP) | VAF 147/318 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- DYSF | c.3828C>G p.L1276= | Silent (SNP) | VAF 84/344 reads (24%) | called by muse, mutect2, varscan2
- LARP1B | c.756G>A p.L252= | Silent (SNP) | VAF 25/418 reads (6%) | called by muse, mutect2
- RPGRIP1L | c.3738C>T p.D1246= | Silent (SNP) | VAF 18/386 reads (5%) | catalogued as rs1239622461, COSV50902801, COSV50921456; called by muse, mutect2
- SLC9A1 | c.763C>T p.L255= | Silent (SNP) | VAF 77/282 reads (27%) | called by muse, mutect2, varscan2
- TCHH | c.3102G>C p.L1034= | Silent (SNP) | VAF 19/426 reads (4%) | called by muse, mutect2
- ADAM22 | c.992+35del | Intron (DEL) | VAF 75/282 reads (27%) | catalogued as rs1345745155; called by mutect2, pindel, varscan2
- PHACTR2 | c.-1G>C | 5'UTR (SNP) | VAF 10/217 reads (5%) | called by muse, mutect2
